Surgical pathology report (de-identified scan), TCGA case TCGA-32-4209, project TCGA-GBM (Glioblastoma Multiforme), tissue source site St. Joseph's Hospital (AZ), specimen TCGA-32-4209-01A (Primary Tumor).

[page 1 of 2]
NEUROPATHOLOGY REPORT

TCGA-32-4209

SPECIMEN SOURCE:

1. Left occipital tumor
2. Left occipital tumor

CLINICAL DIAGNOSIS:

GROSS DESCRIPTION:

1. Received fresh for frozen section are five portions of tan-pink soft tissue ranging in size from 0.1 to 0.4 cm and aggregating to 0.8 x 0.5 x 0.2 cm. A smear preparation is performed. Entirely frozen on one chuck.

FROZEN SECTION DIAGNOSIS:

GLIOBLASTOMA.

The remainder of the previously frozen soft tissue is subsequently submitted for permanent sections.

2. Received in formalin labeled with the patient's name and "left occipital tumor" are multiple fragments of tan-pink soft tissue ranging in size from 0.2 to 0.5 cm in greatest dimension and aggregating to 1.6 x 1.2 x 0.3 cm. The specimen is entirely submitted in one cassette.

MICROSCOPIC DESCRIPTION:

1,2. Sections demonstrate a markedly hypercellular glial neoplasm composed of cells that resemble moderately markedly atypical gemistocytic and, to a lesser degree, fibrillary astrocytes. Numerous scattered mitotic figures are seen. Necrosis, including pseudopalisading necrosis, is present. Microvascular proliferation is also noted. There is multifocal perivascular lymphocytic inflammation. Some of the cells are lipidized, but eosinophilic granular bodies are not seen.

DIAGNOSIS:

1,2. LEFT OCCIPITAL BRAIN TUMOR, BIOPSY AND RESECTION:

[page 2 of 2]
NEUROPATHOLOGY REPORT

DIAGNOSIS:

GLIOBLASTOMA.

[REDACTED]

[REDACTED]

Dictated by:

Verified by:

[REDACTED]

Source: NCI Genomic Data Commons file de75c2aa-b6d4-4b3a-b702-ba5ebc78dbe1 (TCGA-32-4209.9D750B1D-1794-4CEA-8890-075B36048CA4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).